Somatic mutation profile of tumor specimen C3L-06776-09 (aliquot CPT0373490006) from CPTAC case C3L-06776, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G4; Age at diagnosis: 57.2 years (20,906 days).
Specimen C3L-06776-09: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daa2fb48-d0c0-4e8d-a813-915df5d2a211.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06776-31 (Blood Derived Normal), aliquot CPT0374740005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffdac73a-b6ba-4e87-b21a-b8499d3cda8d

The open-access MAF lists 78 somatic variants for this specimen: 54 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 22, Nonsense Mutation 7, Frame Shift Del 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 15/199 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ATP10A | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs375321158; called by muse, mutect2
- CCDC180 | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 25/426 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs375720629; called by muse, mutect2
- CLCN4 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 65/487 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760433125; called by muse, mutect2, varscan2
- DOCK10 | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs748898142, COSV51412858; called by muse, mutect2
- EGR4 | c.1394G>A p.R465H (on ENST00000545030; = p.R362H on NM_001965.4) | Missense Mutation (SNP) | VAF 40/381 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71531929; called by muse, mutect2, varscan2
- EXOSC2 | c.691C>T p.R231* | Nonsense Mutation (SNP) | VAF 24/219 reads (11%) | catalogued as rs149299789; called by muse, mutect2
- FAM47B | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 45/469 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as COSV61452243, COSV61457311; called by mutect2, varscan2
- FAT4 | c.13654G>T p.G4552* | Nonsense Mutation (SNP) | VAF 22/352 reads (6%) | catalogued as COSV58679403; called by muse, mutect2
- FGF14 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.898); catalogued as COSV65944022; called by muse, mutect2
- GCN1 | c.5162C>G p.A1721G | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs1157364046; called by muse, mutect2
- HMCN1 | c.9638G>A p.R3213Q | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1173159547, COSV54901168; called by muse, mutect2
- KANK1 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs1238380516; called by muse, mutect2
- KCNJ8 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 28/364 reads (8%) | catalogued as COSV53715238; called by muse, mutect2
- KCNS3 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 31/390 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.243); catalogued as rs952234451, COSV58405291, COSV58405735; called by muse, mutect2
- MBD5 | c.2998A>G p.T1000A | Missense Mutation (SNP) | VAF 31/384 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs751634567; called by muse, mutect2
- N4BP2 | c.2527T>C p.S843P | Missense Mutation (SNP) | VAF 197/595 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1421777904; called by muse, varscan2
- NYAP1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 43/497 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs878860319, COSV100278749; called by muse, mutect2
- PLCXD1 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 64/494 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs151290083; called by muse, mutect2, varscan2
- PRKCG | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as COSV54726013; called by muse, mutect2
- PSKH2 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs146849251; called by muse, mutect2
- PTPRD | c.3580G>T p.A1194S | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61944849; called by muse, mutect2
- RIT2 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56304950; called by muse, mutect2
- RNF20 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 20/254 reads (8%) | catalogued as rs1418234806; called by muse, mutect2
- ROBO1 | c.346C>A p.R116S | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs777025714, COSV71395496, COSV71398521; called by muse, mutect2
- SHANK3 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53186869; called by muse, mutect2
- TAF1 | c.3482G>A p.R1161H (on ENST00000373790 / NM_138923.4; = p.R1182H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/436 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52111361, COSV99335726; called by muse, mutect2, varscan2
- TG | c.3805G>A p.G1269R | Missense Mutation (SNP) | VAF 27/359 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148963953; called by muse, mutect2
- WNK2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.586); catalogued as rs929246758; called by muse, mutect2
- WNK2 | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1202247284; called by muse, mutect2
- ZFC3H1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1328169911, COSV101110473; called by muse, mutect2
- ZNF623 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 39/582 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.431); catalogued as COSV71697324; called by muse, mutect2
- ZNF625 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs748474291, COSV63241185; called by muse, mutect2
- ZNF831 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 43/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1432505471, COSV64037466; called by muse, mutect2
- ZNF90 | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.314); catalogued as rs781792449, COSV69002747; called by muse, mutect2
- ACTR3 | c.200T>A p.I67K | Missense Mutation (SNP) | VAF 14/233 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- ADAM30 | c.1159A>G p.T387A | Missense Mutation (SNP) | VAF 164/441 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ARHGEF40 | c.2927G>C p.G976A | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- ARID1A | c.5225_5226del p.R1742Nfs*13 | Frame Shift Del (DEL) | VAF 42/310 reads (14%) | called by pindel, varscan2
- BICDL1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CDH6 | c.1712C>A p.S571* | Nonsense Mutation (SNP) | VAF 21/371 reads (6%) | called by muse, mutect2
- DCN | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2
- DTNB | c.1381C>T p.H461Y | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- EPHA6 | c.1218T>A p.C406* | Nonsense Mutation (SNP) | VAF 19/350 reads (5%) | called by muse, mutect2
- KLHL28 | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- N4BP2 | c.2623G>C p.D875H | Missense Mutation (SNP) | VAF 152/446 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- N4BP2 | c.3982_3985delinsAAA p.E1328Kfs*4 | Frame Shift Del (DEL) | VAF 84/318 reads (26%) | called by pindel, varscan2*
- OR9G1 | c.644C>A p.A215D | Missense Mutation (SNP) | VAF 44/700 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2
- PDE2A | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2
- SLC22A8 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2
- SOS2 | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 15/288 reads (5%) | called by muse, mutect2
- SYNDIG1 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 22/441 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.44); called by muse, mutect2
- UTRN | c.9569C>T p.T3190I | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2
- ZXDB | c.2153G>T p.S718I | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ARHGAP5 | c.1749C>T p.R583= | Silent (SNP) | VAF 28/249 reads (11%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.2052C>T p.C684= | Silent (SNP) | VAF 22/356 reads (6%) | catalogued as rs1420226222; called by muse, mutect2
- CTHRC1 | c.105G>A p.K35= | Silent (SNP) | VAF 38/532 reads (7%) | called by muse, mutect2
- CYP4F11 | c.165G>A p.P55= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as rs775052609, COSV56126016; called by muse, mutect2
- DLGAP2 | c.870G>A p.R290= | Silent (SNP) | VAF 52/688 reads (8%) | called by muse, mutect2
- DMD | c.5262G>A p.E1754= | Silent (SNP) | VAF 49/412 reads (12%) | called by muse, mutect2, varscan2
- DOCK4 | c.5790G>A p.A1930= | Silent (SNP) | VAF 42/494 reads (9%) | catalogued as rs1023846795; called by muse, mutect2
- EPHA5 | c.1218G>A p.E406= | Silent (SNP) | VAF 19/289 reads (7%) | catalogued as rs1469602986, COSV56649312, COSV99899269; called by muse, mutect2
- EPHB6 | c.294C>T p.R98= | Silent (SNP) | VAF 44/512 reads (9%) | catalogued as rs773799287, COSV101235943; called by muse, mutect2
- FAM120C | c.291G>A p.A97= | Silent (SNP) | VAF 109/669 reads (16%) | called by muse, mutect2, varscan2
- FAM71B | c.954C>A p.I318= | Silent (SNP) | VAF 22/379 reads (6%) | catalogued as rs1177457807, COSV100262098, COSV57229467; called by muse, mutect2
- GABBR1 | c.2649C>T p.N883= | Silent (SNP) | VAF 60/568 reads (11%) | catalogued as rs753549467, COSV100589367; ClinVar: likely benign; called by muse, mutect2
- GPI | c.861C>T p.H287= | Silent (SNP) | VAF 34/348 reads (10%) | catalogued as rs371025511; called by muse, mutect2
- H1-5 | c.537C>T p.A179= | Silent (SNP) | VAF 28/426 reads (7%) | catalogued as rs146157091; called by muse, mutect2
- KAZN | c.165C>T p.S55= | Silent (SNP) | VAF 82/434 reads (19%) | called by muse, varscan2
- KPRP | c.966C>A p.G322= | Silent (SNP) | VAF 34/492 reads (7%) | catalogued as COSV64221091, COSV64221342; called by muse, mutect2
- MSANTD1 | c.585C>T p.S195= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- PRAG1 | c.27C>T p.P9= | Silent (SNP) | VAF 18/282 reads (6%) | catalogued as rs750054213, COSV100422023; called by muse, mutect2
- SH3GL3 | c.540C>T p.D180= | Silent (SNP) | VAF 19/396 reads (5%) | catalogued as rs138675150; called by muse, mutect2
- SLC25A13 | c.486C>T p.H162= | Silent (SNP) | VAF 31/259 reads (12%) | catalogued as rs1562831788, COSV99673663; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFSF11 | c.571C>A p.R191= | Silent (SNP) | VAF 20/311 reads (6%) | catalogued as rs779363839, COSV53478697; called by muse, mutect2
- TTN | c.2292C>T p.V764= (on ENST00000591111; = p.V718= on NM_003319.4) | Silent (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- MARCHF9 | c.514-139C>T | Intron (SNP) | VAF 30/352 reads (9%) | catalogued as rs749112651; called by muse, mutect2
- RGS10 | c.49+6122G>A | Intron (SNP) | VAF 16/302 reads (5%) | called by muse, mutect2
